Somatic mutation profile of tumor specimen HCM-CSHL-0183-C25-01A (aliquot HCM-CSHL-0183-C25-01A-11D-A78L-36) from HCMI case HCM-CSHL-0183-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.0 years (23,374 days).
Specimen HCM-CSHL-0183-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7240dd0f-b0c8-469d-b53c-47ef7d0b8454.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0183-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0183-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c62988ff-29e7-4b6c-9001-3acdcfe7eed8

The open-access MAF lists 78 somatic variants for this specimen: 46 protein-altering or splice-affecting, 20 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 20, Intron 5, 3'Flank 3, Frame Shift Del 2, RNA 2, Splice Site 1, 3'UTR 1, In Frame Del 1, 5'Flank 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 67/296 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 75/286 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.3496G>A p.V1166I | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs538139197, COSV67140479; called by muse, varscan2
- ADCY8 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 107/605 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs753815200, COSV53913774; called by muse, mutect2, varscan2
- ARHGAP22 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs775119246, COSV99984915; called by muse, mutect2, varscan2
- EFCAB6 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 37/156 reads (24%) | catalogued as rs772599532, COSV53060948; called by muse, mutect2, varscan2
- ENOX2 | c.850C>T p.R284C (on ENST00000338144 / NM_001382520.1; = p.R255C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1391870850; called by muse, mutect2, varscan2
- FBXL7 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 79/380 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs771652620, COSV61647711; called by muse, mutect2, varscan2
- HYDIN | c.2429A>G p.N810S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1017138844; called by mutect2, varscan2
- KAT8 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54899483; called by muse, mutect2, varscan2
- KCNK9 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 96/506 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV57279943; called by muse, mutect2, varscan2
- KLHL25 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs374266297; called by muse, varscan2
- LPIN1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 106/580 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as CD103916; called by muse, mutect2, varscan2
- NCOA3 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772403773, COSV59067229; called by muse, mutect2, varscan2
- NKAP | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65056547; called by muse, mutect2, varscan2
- NRXN1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.2); catalogued as rs796052775, COSV68014124; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDIA2 | c.1533G>A p.P511= | Splice Region (SNP) | VAF 11/71 reads (15%) | catalogued as rs571293134; called by muse, mutect2, varscan2
- PPP2R1B | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs888625399, COSV100232178, COSV59536995; called by muse, mutect2, varscan2
- PTPRK | c.3193C>T p.R1065W (on ENST00000368215 / NM_001291984.2; = p.R1066W on NM_002844.4) | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757577999, COSV100950250; called by muse, mutect2, varscan2
- RP1 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 60/377 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV55114654, COSV55116485, COSV55120087; called by muse, mutect2, varscan2
- RTN2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV99838857; called by muse, mutect2
- SH3GL1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.309); catalogued as rs1460227872; called by muse, mutect2, varscan2
- SMAD4 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060500743, COSV61683986, COSV61688959, COSV61693892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN2 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs377045177; called by muse, mutect2, varscan2
- TMEM63B | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs773890282, COSV99442126; called by muse, mutect2, varscan2
- TMPRSS11F | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.99); catalogued as rs199559743, COSV100678692; called by muse, mutect2, varscan2
- TRIM75P | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs376399427; called by muse, varscan2
- WTIP | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs377447205; called by muse, mutect2, varscan2
- ZNF648 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV60570840; called by muse, mutect2, varscan2
- ZNF777 | c.2132G>T p.R711L | Missense Mutation (SNP) | VAF 68/289 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as COSV56096557, COSV56098603; called by muse, mutect2, varscan2
- AL133500.1 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 79/362 reads (22%) | SIFT tolerated, low confidence (0.2); called by muse, mutect2, varscan2
- ARID1A | c.5089_5124+8del p.X1697_splice | Splice Site (DEL) | VAF 42/246 reads (17%) | called by mutect2, pindel
- CYP26C1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- DEGS2 | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAAP20 | c.283T>C p.W95R | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGFR2 | c.2005T>C p.W669R | Missense Mutation (SNP) | VAF 94/477 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HACE1 | c.48_61del p.R17Gfs*6 | Frame Shift Del (DEL) | VAF 60/361 reads (17%) | called by mutect2, pindel, varscan2
- HOXB1 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ILF3 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- JAG1 | c.2872T>G p.C958G | Missense Mutation (SNP) | VAF 105/443 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIF21B | c.2876G>C p.R959T | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAGEB2 | c.341A>C p.K114T | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2
- POLR3H | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 55/293 reads (19%) | called by mutect2, pindel, varscan2
- TNS4 | c.2073G>C p.E691D | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF746 | c.1474_1482del p.S492_G494del | In Frame Del (DEL) | VAF 37/244 reads (15%) | called by mutect2, pindel, varscan2
- ABRA | c.462C>T p.H154= | Silent (SNP) | VAF 61/282 reads (22%) | catalogued as rs546797793, COSV61733918; called by muse, mutect2, varscan2
- AK1 | c.546C>A p.V182= | Silent (SNP) | VAF 101/432 reads (23%) | called by muse, mutect2, varscan2
- CAPN6 | c.1905C>T p.S635= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as rs921083346, COSV100137003; called by muse, mutect2, varscan2
- COL11A1 | c.420A>G p.E140= | Silent (SNP) | VAF 22/285 reads (8%) | called by muse, mutect2
- DCAF12L1 | c.141G>A p.T47= | Silent (SNP) | VAF 77/366 reads (21%) | catalogued as COSV64422083; called by muse, mutect2, varscan2
- DDOST | c.438G>C p.G146= (on ENST00000415136; = p.G129= on NM_005216.5) | Silent (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- KCNAB3 | c.90C>T p.G30= | Silent (SNP) | VAF 89/319 reads (28%) | catalogued as rs1268985172; called by muse, mutect2, varscan2
- KIAA1614 | c.378C>T p.A126= | Silent (SNP) | VAF 27/245 reads (11%) | catalogued as rs375439826; called by muse, mutect2, varscan2
- KRT79 | c.384T>C p.H128= | Silent (SNP) | VAF 72/329 reads (22%) | catalogued as rs531448774; called by muse, mutect2, varscan2
- MBIP | c.582T>C p.C194= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- MUC12 | c.12735A>G p.E4245= (on ENST00000379442; = p.E4102= on NM_001164462.1) | Silent (SNP) | VAF 193/547 reads (35%) | called by muse, mutect2, varscan2
- MXRA5 | c.6471C>T p.D2157= | Silent (SNP) | VAF 31/185 reads (17%) | catalogued as rs1335154162; called by muse, mutect2, varscan2
- MYT1 | c.3183C>T p.S1061= | Silent (SNP) | VAF 41/214 reads (19%) | catalogued as rs1273170188, COSV60501160; called by muse, mutect2, varscan2
- OR1A1 | c.723T>C p.G241= | Silent (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- PCDH15 | c.1317A>G p.P439= | Silent (SNP) | VAF 67/322 reads (21%) | catalogued as rs768151894; called by muse, mutect2, varscan2
- PCDHA3 | c.213C>T p.H71= | Silent (SNP) | VAF 147/504 reads (29%) | catalogued as rs138112183, COSV65366172; called by muse, mutect2, varscan2
- RSPH10B2 | c.189C>T p.N63= | Silent (SNP) | VAF 99/757 reads (13%) | catalogued as rs753432937; called by muse, mutect2, varscan2
- SPTBN5 | c.4314C>T p.L1438= | Silent (SNP) | VAF 39/161 reads (24%) | catalogued as rs762819167, COSV58028988; called by muse, mutect2, varscan2
- TBKBP1 | c.21C>T p.D7= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as rs373991355; called by muse, mutect2, varscan2
- VPS13C | c.5877A>T p.G1959= (on ENST00000644861 / NM_020821.3; = p.G1916= on NM_017684.5) | Silent (SNP) | VAF 26/133 reads (20%) | called by muse, mutect2, varscan2
- AC103996.1 | chr15:93821050 T>A | 3'Flank (SNP) | VAF 43/294 reads (15%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500844 del GGG | 5'Flank (DEL) | VAF 29/163 reads (18%) | catalogued as rs772360578; called by mutect2, pindel, varscan2
- CADPS | c.*2C>G | 3'UTR (SNP) | VAF 19/94 reads (20%) | called by muse, varscan2
- DAW1 | c.973+5183A>G | Intron (SNP) | VAF 43/195 reads (22%) | called by muse, mutect2, varscan2
- FAM90A27P | n.1231C>T | RNA (SNP) | VAF 23/244 reads (9%) | called by muse, mutect2
- FNTA | c.783-12_783-11insA | Intron (INS) | VAF 10/83 reads (12%) | called by pindel, varscan2
- MED13L | c.2238+20_2238+21insGG | Intron (INS) | VAF 33/265 reads (12%) | called by mutect2, pindel, varscan2
- MIR154 | n.13G>A | RNA (SNP) | VAF 69/338 reads (20%) | called by muse, mutect2, varscan2
- MIR6511A1 | chr16:14929398 A>G | 3'Flank (SNP) | VAF 125/1277 reads (10%) | catalogued as rs528377283; called by muse, mutect2, varscan2
- PLEKHS1 | chr10:113780764 del AAAGGAGCCAGGGAGT | 3'Flank (DEL) | VAF 18/134 reads (13%) | called by mutect2, pindel
- TXNRD1 | c.415-1272T>G | Intron (SNP) | VAF 52/215 reads (24%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-3383A>G | Intron (SNP) | VAF 38/201 reads (19%) | catalogued as rs891088251; called by muse, mutect2, varscan2
